Somatic mutation profile of tumor specimen MP2PRT-PAPVDC-TMP1-A (aliquot MP2PRT-PAPVDC-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPVDC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,614 days).
Specimen MP2PRT-PAPVDC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bed412b3-fab0-42c2-80d0-9dff51290eae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPVDC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPVDC-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64eb47ef-8b9d-4af4-9f7c-3d27a2b43c1e

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Ins 1, Splice Region 1, In Frame Del 1, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54655701; called by muse, mutect2
- CHD5 | c.1696G>A p.E566K | Missense Mutation (SNP) | VAF 21/662 reads (3%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.959); catalogued as rs1368579320, COSV52420590; called by muse, mutect2
- DGKB | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs562219154, COSV51790648, COSV51815168; called by muse, mutect2, varscan2
- DNAH1 | c.5097G>A p.A1699= | Splice Region (SNP) | VAF 159/325 reads (49%) | catalogued as rs974198069, COSV70226954; called by muse, mutect2, varscan2
- FAM83H | c.2957G>A p.G986D | Missense Mutation (SNP) | VAF 26/938 reads (3%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1173375836; called by muse, mutect2
- NEUROD4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 238/528 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139282092; called by muse, mutect2, varscan2
- ATM | c.5428A>C p.T1810P | Missense Mutation (SNP) | VAF 87/95 reads (92%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CCKAR | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 188/403 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HIBCH | c.107A>G p.E36G | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-45 | c.352_353insGG | In Frame Ins (INS) | VAF 91/219 reads (42%) | called by mutect2, pindel*, varscan2*
- IGHV1-69 | chr14:106714664 GTGGGTTTTCACACTGTGTCTCTC>CCCGT | Missense Mutation (DEL) | VAF 86/132 reads (65%) | called by muse*, pindel
- IGHV3-53 | c.349_350insGGTAAGAC | Nonsense Mutation (INS) | VAF 18/34 reads (53%) | called by mutect2, pindel*
- IGKV2D-24 | c.359_360insCCCCCCC p.*121Pfs*? | Frame Shift Ins (INS) | VAF 16/114 reads (14%) | called by pindel, varscan2
- IRF2BPL | c.554_556del p.H185_T186delinsP | In Frame Del (DEL) | VAF 217/626 reads (35%) | called by pindel*, varscan2
- L3MBTL4 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 35/623 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.051); called by muse, mutect2
- LY6H | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 49/1036 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.2); called by muse, mutect2
- MUC12 | c.13425G>T p.W4475C (on ENST00000379442; = p.W4332C on NM_001164462.1) | Missense Mutation (SNP) | VAF 216/3322 reads (7%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2
- TTN | c.74749G>C p.E24917Q (on ENST00000591111; = p.E17493Q on NM_003319.4) | Missense Mutation (SNP) | VAF 29/345 reads (8%) | PolyPhen benign (0.067); called by muse, mutect2
- FGD1 | c.909C>T p.D303= | Silent (SNP) | VAF 116/449 reads (26%) | catalogued as rs142333892, COSV64308332; called by muse, mutect2, varscan2
- KCNK2 | c.1005C>T p.N335= (on ENST00000444842 / NM_001017425.3; = p.N320= on NM_014217.4) | Silent (SNP) | VAF 67/475 reads (14%) | catalogued as rs766296960, COSV67204479; called by muse, mutect2, varscan2
- KIF7 | c.585C>G p.L195= | Silent (SNP) | VAF 42/852 reads (5%) | called by muse, mutect2
- RGS7 | c.582A>G p.R194= | Silent (SNP) | VAF 217/454 reads (48%) | called by muse, mutect2, varscan2
- SON | c.1170C>T p.S390= | Silent (SNP) | VAF 82/900 reads (9%) | called by muse, mutect2
